Somatic mutation profile of tumor specimen TCGA-Y8-A895-01A (aliquot TCGA-Y8-A895-01A-11D-A35Z-10) from TCGA case TCGA-Y8-A895, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.3 years (27,139 days).
Specimen TCGA-Y8-A895-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01011797-ff1c-43d8-855e-f4a6a8886919.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A895-10A (Blood Derived Normal), aliquot TCGA-Y8-A895-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cef289ce-c496-4e94-8073-e3d43a19c333

The open-access MAF lists 102 somatic variants for this specimen: 81 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Frame Shift Del 8, Nonsense Mutation 7, Frame Shift Ins 6, Splice Site 1, 3'Flank 1, Intron 1, In Frame Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV100272374; called by muse, mutect2, varscan2
- AKAP4 | c.2183C>A p.A728E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV100654319; called by muse, mutect2, varscan2
- ANKS4B | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289896; called by muse, mutect2, varscan2
- BAZ2A | c.4415A>C p.H1472P | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV99466989; called by muse, mutect2, varscan2
- BCR | c.2755T>G p.S919A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV100006767; called by muse, mutect2, varscan2
- BEST1 | c.1619A>G p.N540S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99861356; called by muse, mutect2, varscan2
- C11orf1 | c.82T>A p.C28S | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99500109; called by muse, mutect2, varscan2
- C2orf78 | c.2758T>C p.Y920H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101281013; called by muse, mutect2, varscan2
- CACNA1A | c.3796G>A p.A1266T | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs776503550, COSV100802928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPA | c.4944G>T p.R1648S (on ENST00000334218 / NM_001366019.2; = p.R1635S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV100506203; called by muse, mutect2, varscan2
- CDC7 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs539320135, COSV52310602; called by muse, varscan2
- CEP135 | c.1874A>T p.Y625F | Missense Mutation (SNP) | VAF 169/441 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99954712; called by muse, mutect2, varscan2
- CRTC2 | c.1558T>G p.S520A | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100339244; called by muse, mutect2, varscan2
- DCAF8 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100470672; called by muse, mutect2, varscan2
- DNAH8 | c.7307T>G p.I2436S | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100546489, COSV100547390; called by muse, mutect2, varscan2
- EML5 | c.3631G>T p.G1211W | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100715867; called by muse, mutect2, varscan2
- EPS8L2 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV100585632; called by muse, mutect2, varscan2
- EVI5 | c.2076T>G p.Y692* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100945449; called by muse, mutect2, varscan2
- FAM13C | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99514282; called by muse, mutect2, varscan2
- FAM20C | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100570534; called by muse, mutect2, varscan2
- FLVCR2 | c.315C>G p.Y105* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as rs746197249, COSV53164479; called by muse, mutect2, varscan2
- FO393400.1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV54071407, COSV99640754; called by muse, mutect2, varscan2
- GLUD1 | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99518303; called by muse, mutect2, varscan2
- GPR151 | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99695093; called by muse, mutect2, varscan2
- HERC1 | c.2822C>A p.A941D | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101496748; called by muse, mutect2, varscan2
- HERC2 | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99875525; called by muse, mutect2, varscan2
- HMX3 | c.513C>G p.S171R | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100774153; called by muse, mutect2, varscan2
- HOXD10 | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99982191; called by muse, mutect2, varscan2
- IL4R | c.2141C>A p.S714* | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | catalogued as COSV99405224; called by muse, mutect2, varscan2
- KCNK10 | c.408T>G p.N136K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.314); catalogued as COSV100068901; called by muse, mutect2, varscan2
- KIF3A | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV101109455; called by muse, mutect2, varscan2
- KIF5A | c.1879T>A p.S627T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV99673310; called by muse, mutect2
- KLHL26 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.953); catalogued as rs769972361, COSV56318585; called by muse, mutect2, varscan2
- LTBP3 | c.2741A>G p.H914R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as COSV99534393; called by muse, mutect2, varscan2
- LTF | c.2102T>A p.L701H | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99209932; called by muse, mutect2, varscan2
- MTMR2 | c.1136G>T p.W379L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100656794; called by muse, mutect2, varscan2
- MYH7B | c.3684G>T p.E1228D | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52682193, COSV99328695; called by muse, mutect2, varscan2
- NOL9 | c.2012T>G p.L671R | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100891495; called by muse, mutect2, varscan2
- PHIP | c.3493T>C p.C1165R | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99244606; called by muse, mutect2, varscan2
- PKD1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as COSV99238627; called by muse, mutect2, varscan2
- PLCZ1 | c.902T>A p.I301K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV99856642; called by muse, mutect2, varscan2
- RAPGEF5 | c.589C>T p.Q197* (on ENST00000401957 / NM_001367602.2; = p.Q500* on NM_012294.5) | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as COSV59795652; called by muse, mutect2, varscan2
- RFX4 | c.908A>G p.E303G (on ENST00000392842 / NM_213594.3; = p.E209G on NM_032491.6) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57579001; called by muse, mutect2, varscan2
- SCN3B | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100173810; called by muse, mutect2, varscan2
- SEPTIN10 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.433); catalogued as COSV100454210; called by muse, mutect2, varscan2
- SETDB1 | c.3543C>A p.N1181K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV99645400; called by muse, mutect2
- SHISA3 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV100069893; called by muse, mutect2, varscan2
- SLC15A4 | c.1034A>G p.Q345R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99903712; called by muse, mutect2, varscan2
- SLCO1A2 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 39/118 reads (33%) | catalogued as COSV100262374, COSV56602664; called by muse, mutect2, varscan2
- SMU1 | c.1301G>T p.S434I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV101238560; called by muse, mutect2, varscan2
- SORL1 | c.3015G>T p.M1005I | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV99494780; called by muse, mutect2, varscan2
- SV2A | c.1075C>G p.R359G | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100975223; called by muse, mutect2, varscan2
- SYNE1 | c.10810G>C p.E3604Q (on ENST00000367255 / NM_182961.4; = p.E3611Q on NM_033071.3) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99572924; called by muse, mutect2, varscan2
- TACC2 | c.4135G>C p.E1379Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV100553173; called by muse, mutect2, varscan2
- TFAP2B | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99540593; called by muse, mutect2, varscan2
- TROAP | c.216del p.R73Gfs*46 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | catalogued as COSV99226914; called by mutect2, varscan2
- ZNF546 | c.1955T>A p.L652H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100713516; called by muse, mutect2, varscan2
- ZNF552 | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 56/184 reads (30%) | catalogued as COSV101197548; called by muse, mutect2, varscan2
- ZNF600 | c.2082C>G p.Y694* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | catalogued as COSV100593052; called by muse, mutect2, varscan2
- ZNF671 | c.267A>T p.G89= | Splice Region (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100235182; called by muse, mutect2, varscan2
- ZNF687 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100134430; called by muse, mutect2, varscan2
- ZNF76 | c.1495-1G>A p.X499_splice | Splice Site (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99987806; called by muse, mutect2, varscan2
- ZNF790 | c.1297T>G p.W433G | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.294); catalogued as COSV100764861; called by muse, mutect2, varscan2
- ANGPT1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ANGPT1 | c.108T>G p.I36M | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CFAP69 | c.2417_2420del p.S806Kfs*43 | Frame Shift Del (DEL) | VAF 151/307 reads (49%) | called by mutect2, varscan2
- COG3 | c.398del p.Y133Sfs*13 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- CSMD3 | c.3158dup p.N1053Kfs*12 (on ENST00000297405 / NM_001363185.1; = p.N949Kfs*12 on NM_052900.3) | Frame Shift Ins (INS) | VAF 23/209 reads (11%) | called by mutect2, varscan2
- DNAH9 | c.3600_3601dup p.I1201Tfs*2 | Frame Shift Ins (INS) | VAF 59/237 reads (25%) | called by mutect2, pindel, varscan2
- FADS3 | c.1012_1021del p.I338* | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- GNA14 | c.671del p.F224Sfs*5 | Frame Shift Del (DEL) | VAF 44/125 reads (35%) | called by mutect2, pindel, varscan2
- HSCB | c.-2_2del | Translation Start Site (DEL) | VAF 35/65 reads (54%) | called by mutect2, pindel, varscan2
- IGKV2-24 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 138/399 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MIDN | c.253dup p.L85Pfs*8 | Frame Shift Ins (INS) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- MYH11 | c.3842_3843dup p.V1282Kfs*177 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- PLAG1 | c.1055dup p.L352Ffs*6 | Frame Shift Ins (INS) | VAF 38/101 reads (38%) | called by mutect2, pindel, varscan2
- RETREG3 | c.249_254del p.L84_T85del | In Frame Del (DEL) | VAF 31/57 reads (54%) | called by mutect2, pindel, varscan2
- SLC34A1 | c.883_890dup p.R297Sfs*3 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | called by mutect2, varscan2
- TASOR | c.2007del p.R669Sfs*16 (on ENST00000355628 / NM_001365636.2; = p.R273Sfs*16 on NM_015224.3) | Frame Shift Del (DEL) | VAF 66/142 reads (46%) | called by mutect2, pindel, varscan2
- THY1 | c.175_182del p.K59Rfs*10 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- TMEM190 | c.414_420del p.P139Rfs*? | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by pindel, varscan2
- DSP | c.2949C>G p.T983= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV101131539; called by muse, mutect2, varscan2
- EPN1 | c.834C>G p.G278= (on ENST00000270460 / NM_001321263.1; = p.G253= on NM_013333.3) | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV99322153; called by muse, varscan2
- GRM1 | c.1995C>T p.G665= | Silent (SNP) | VAF 56/123 reads (46%) | catalogued as COSV99267746; called by muse, mutect2, varscan2
- HIPK3 | c.2832T>C p.S944= | Silent (SNP) | VAF 22/277 reads (8%) | catalogued as COSV100305922; called by muse, mutect2
- HS1BP3 | c.339T>C p.N113= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1179588240, COSV100398047; called by muse, mutect2, varscan2
- HSP90AA1 | c.990A>G p.S330= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV99355416; called by muse, varscan2
- LMF1 | c.870C>A p.I290= | Silent (SNP) | VAF 47/213 reads (22%) | catalogued as rs756988851, COSV99235616; called by muse, mutect2, varscan2
- LRP1 | c.11703C>T p.R3901= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV99676588; called by muse, mutect2, varscan2
- MCM2 | c.1617G>A p.V539= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as COSV99413306; called by muse, mutect2, varscan2
- MED13L | c.528T>C p.N176= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs1269674863, COSV99929573; called by muse, mutect2, varscan2
- RPA1 | c.1288C>T p.L430= | Silent (SNP) | VAF 47/222 reads (21%) | catalogued as COSV99628202; called by muse, mutect2, varscan2
- SERPINF2 | c.582G>A p.T194= | Silent (SNP) | VAF 101/181 reads (56%) | catalogued as rs78558219, COSV100132041; called by muse, mutect2, varscan2
- SMYD3 | c.1062C>T p.T354= (on ENST00000490107 / NM_001375962.1; = p.T295= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100830834; called by muse, mutect2, varscan2
- TAMM41 | c.798T>A p.P266= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV99808890; called by muse, mutect2, varscan2
- TBC1D16 | c.153G>A p.G51= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as rs1198146419, COSV100188280; called by muse, mutect2, varscan2
- TRGC1 | c.243A>G p.S81= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- UNC13A | c.3690C>T p.L1230= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99409033; called by muse, mutect2, varscan2
- ZNF444 | c.936T>A p.A312= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100442700; called by muse, mutect2, varscan2
- ZNF774 | c.837C>T p.I279= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100586411; called by muse, mutect2
- TSPAN14 | chr10:80520764 G>T | 3'Flank (SNP) | VAF 43/109 reads (39%) | catalogued as COSV99627892; called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1768A>C | Intron (SNP) | VAF 52/141 reads (37%) | catalogued as COSV99193163; called by muse, mutect2, varscan2
